Somatic mutation profile of tumor specimen MMRF_2329_1_BM_CD138pos (aliquot MMRF_2329_1_BM_CD138pos_T1_KHS5U_L09541) from MMRF case MMRF_2329, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 72.1 years (26,324 days).
Specimen MMRF_2329_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cbdcbf45-7e7a-4bb2-a8c3-77c5b80ccaa7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2329_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2329_1_PB_Whole_C3_KHS5U_L09542; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f618985c-8a26-4af2-bda5-362b31165a93

The open-access MAF lists 101 somatic variants for this specimen: 41 protein-altering or splice-affecting, 12 silent, 48 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, 3'UTR 29, Intron 12, Silent 12, 5'UTR 5, Nonsense Mutation 2, RNA 2, Splice Region 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 44/88 reads (50%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATR | c.1402C>T p.Q468* | Nonsense Mutation (SNP) | VAF 17/111 reads (15%) | catalogued as rs1411907335; called by muse, mutect2, varscan2
- CFAP20DC | c.1690C>T p.R564W | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs987580223; called by muse, mutect2, varscan2
- DPP6 | c.627+1G>A p.X209_splice (on ENST00000377770 / NM_001364500.2; = p.X147_splice on NM_001936.5) | Splice Site (SNP) | VAF 55/84 reads (65%) | catalogued as rs747569022, CS142914; called by muse, mutect2, varscan2
- EIF3E | c.268C>T p.P90S | Missense Mutation (SNP) | VAF 66/182 reads (36%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.461); catalogued as rs1315509381; called by muse, mutect2, varscan2
- GLI2 | c.671C>T p.T224M | Missense Mutation (SNP) | VAF 107/254 reads (42%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.54); catalogued as rs370333257; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IGHV2-70 | c.161G>A p.C54Y | Missense Mutation (SNP) | VAF 58/98 reads (59%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs368641348; called by muse, varscan2
- IGKV4-1 | c.229G>C p.A77P | Missense Mutation (SNP) | VAF 32/40 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs758803569; called by muse, mutect2, varscan2
- IGLL5 | c.116T>C p.L39P | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as rs532234272, COSV73249744; called by muse, varscan2
- ILVBL | c.1634T>C p.V545A | Missense Mutation (SNP) | VAF 68/248 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as COSV99654643; called by muse, varscan2
- KANK4 | c.2356C>T p.R786C | Missense Mutation (SNP) | VAF 60/134 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.372); catalogued as rs1390022806, COSV58093929; called by muse, mutect2
- KCNQ3 | c.114C>G p.D38E | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0.014); catalogued as rs1477607835; called by muse, mutect2, varscan2
- MOGAT3 | c.656C>T p.A219V | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.68); catalogued as COSV56174032; called by muse, mutect2, varscan2
- PCDH7 | c.850G>A p.G284S | Missense Mutation (SNP) | VAF 38/217 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780929028, COSV62343115; called by muse, mutect2, varscan2
- RACK1 | c.525+7G>A | Splice Region (SNP) | VAF 66/184 reads (36%) | catalogued as rs749437109; called by muse, mutect2, varscan2
- SCN9A | c.5579G>A p.R1860H (on ENST00000303354; = p.R1849H on NM_002977.3) | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.091); catalogued as rs766124857, COSV100312733; called by muse, mutect2, varscan2
- STON1 | c.310C>T p.P104S | Missense Mutation (SNP) | VAF 61/155 reads (39%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.311); catalogued as COSV59131231; called by muse, mutect2, varscan2
- TBC1D8 | c.1855C>T p.R619W | Missense Mutation (SNP) | VAF 19/153 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755195520, COSV65214343; called by muse, mutect2, varscan2
- TIAM1 | c.1973C>T p.S658L | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as rs1462610021, COSV54555018; called by muse, mutect2, varscan2
- TRIM29 | c.1270G>A p.V424I | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.16); catalogued as rs373220023, COSV59281084; called by muse, mutect2, varscan2
- ZCWPW1 | c.1283G>A p.R428Q | Missense Mutation (SNP) | VAF 53/159 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs955190979, COSV99546589; called by muse, mutect2, varscan2
- ABCA13 | c.11177T>A p.I3726N | Missense Mutation (SNP) | VAF 57/173 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ATR | c.7769C>A p.T2590N | Missense Mutation (SNP) | VAF 97/309 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- CD1A | c.615G>C p.E205D | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- CD36 | c.722G>C p.S241T | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT tolerated (0.71); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- CXXC1 | c.868C>G p.L290V | Missense Mutation (SNP) | VAF 9/174 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.636); called by muse, mutect2
- EIF2S2 | c.920C>T p.S307F | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- ESRRG | c.11T>C p.V4A | Missense Mutation (SNP) | VAF 67/358 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- GPR83 | c.428T>C p.M143T | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- HNRNPU | c.91A>G p.K31E | Missense Mutation (SNP) | VAF 14/137 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- IGHA1 | c.504_520del p.K168Nfs*3 | Frame Shift Del (DEL) | VAF 6/54 reads (11%) | called by mutect2, varscan2
- IGHV2-70D | c.235T>G p.F79V | Missense Mutation (SNP) | VAF 34/37 reads (92%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, varscan2
- IGLON5 | c.230A>T p.D77V | Missense Mutation (SNP) | VAF 11/245 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- IZUMO3 | c.83T>A p.F28Y | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT tolerated (0.13); called by muse, mutect2, varscan2
- LRIF1 | c.1622C>A p.S541* | Nonsense Mutation (SNP) | VAF 15/299 reads (5%) | called by muse, mutect2
- LRRIQ1 | c.2761T>C p.S921P | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- MAN2C1 | c.510G>A p.M170I | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NUP153 | c.2819C>T p.S940F | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- PTPRQ | c.3605A>T p.K1202I (on ENST00000616559; = p.K1160I on NM_001145026.2) | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- TASOR | c.889C>T p.L297F | Missense Mutation (SNP) | VAF 89/155 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- TMEM132C | c.3047G>A p.G1016D | Missense Mutation (SNP) | VAF 58/132 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.009); called by muse, varscan2
- ATP1A3 | c.1812C>T p.D604= (on ENST00000545399 / NM_001256214.2; = p.D591= on NM_152296.5) | Silent (SNP) | VAF 9/156 reads (6%) | catalogued as rs782220233, COSV100131954; ClinVar: likely benign; called by muse, mutect2
- ATP6V1F | c.109C>T p.L37= | Silent (SNP) | VAF 72/223 reads (32%) | called by muse, mutect2, varscan2
- CCDC157 | c.1951C>T p.L651= | Silent (SNP) | VAF 47/94 reads (50%) | called by muse, mutect2, varscan2
- DLX5 | c.813G>A p.L271= | Silent (SNP) | VAF 27/219 reads (12%) | called by muse, mutect2, varscan2
- FBXL7 | c.1212C>G p.L404= | Silent (SNP) | VAF 64/211 reads (30%) | called by muse, mutect2, varscan2
- ILVBL | c.1701C>T p.A567= | Silent (SNP) | VAF 62/210 reads (30%) | catalogued as COSV99655001; called by muse, varscan2
- KPRP | c.801C>A p.R267= | Silent (SNP) | VAF 33/262 reads (13%) | called by muse, mutect2, varscan2
- OR13D1 | c.474C>A p.I158= | Silent (SNP) | VAF 35/94 reads (37%) | called by muse, mutect2, varscan2
- OR1J1 | c.660C>T p.H220= | Silent (SNP) | VAF 15/221 reads (7%) | catalogued as rs1564173528; called by muse, mutect2
- RTBDN | c.45G>A p.V15= (on ENST00000393233 / NM_001270444.1; = p.V47= on NM_031429.2) | Silent (SNP) | VAF 10/121 reads (8%) | called by muse, mutect2
- SVEP1 | c.3213G>T p.S1071= | Silent (SNP) | VAF 40/133 reads (30%) | catalogued as rs780701958; called by muse, mutect2, varscan2
- TRIR | c.339T>G p.L113= | Silent (SNP) | VAF 29/94 reads (31%) | called by muse, mutect2, varscan2
- AGRN | c.5652-43T>C | Intron (SNP) | VAF 8/15 reads (53%) | called by muse, mutect2, varscan2
- AGXT2 | c.871-60del | Intron (DEL) | VAF 31/103 reads (30%) | called by mutect2, pindel, varscan2
- AKAP12 | c.-164del | 5'UTR (DEL) | VAF 9/37 reads (24%) | called by mutect2, pindel, varscan2
- AL121757.1 | n.319C>T | RNA (SNP) | VAF 12/54 reads (22%) | called by muse, mutect2, varscan2
- ALPL | c.*148C>T | 3'UTR (SNP) | VAF 52/140 reads (37%) | called by muse, mutect2, varscan2
- APBB2 | c.*4884G>T | 3'UTR (SNP) | VAF 15/83 reads (18%) | called by muse, mutect2, varscan2
- APBB2 | c.*2590C>A | 3'UTR (SNP) | VAF 22/142 reads (15%) | called by muse, mutect2, varscan2
- ATF6 | c.*3125A>T | 3'UTR (SNP) | VAF 4/41 reads (10%) | called by muse, mutect2
- ATP6AP2 | c.*861_*864del | 3'UTR (DEL) | VAF 8/17 reads (47%) | catalogued as rs1156967644; called by mutect2, varscan2
- ATP8B3 | c.*632C>T | 3'UTR (SNP) | VAF 19/154 reads (12%) | catalogued as rs897779452; called by muse, mutect2, varscan2
- BICC1 | c.*506T>G | 3'UTR (SNP) | VAF 47/97 reads (48%) | called by muse, mutect2, varscan2
- C5orf15 | c.*647T>C | 3'UTR (SNP) | VAF 5/63 reads (8%) | called by muse, mutect2
- CALM1 | c.*621G>A | 3'UTR (SNP) | VAF 38/79 reads (48%) | catalogued as rs187714594; called by muse, mutect2, varscan2
- CFAP251 | c.2772-3426G>A | Intron (SNP) | VAF 8/57 reads (14%) | catalogued as rs1404494390; called by mutect2, varscan2
- DAAM2 | c.*439C>A | 3'UTR (SNP) | VAF 8/140 reads (6%) | called by muse, mutect2
- ENTPD8 | c.555+22C>T | Intron (SNP) | VAF 43/168 reads (26%) | catalogued as rs375691923; called by muse, mutect2, varscan2
- EYS | c.-121dup | 5'UTR (INS) | VAF 16/92 reads (17%) | called by mutect2, pindel, varscan2
- FECH | c.*99C>G | 3'UTR (SNP) | VAF 19/42 reads (45%) | called by muse, mutect2, varscan2
- FGF17 | c.*5G>A | 3'UTR (SNP) | VAF 13/22 reads (59%) | called by muse, mutect2, varscan2
- GRAMD2B | c.*1221G>T | 3'UTR (SNP) | VAF 36/114 reads (32%) | called by muse, mutect2, varscan2
- GRIK3 | c.*144C>T | 3'UTR (SNP) | VAF 15/43 reads (35%) | called by muse, mutect2, varscan2
- HOXB13 | c.*1484G>T | 3'UTR (SNP) | VAF 15/125 reads (12%) | called by muse, mutect2, varscan2
- IGLL5 | c.-89A>G | 5'UTR (SNP) | VAF 32/62 reads (52%) | catalogued as COSV101597191; called by muse, mutect2, varscan2
- KRT4 | c.*312G>C | 3'UTR (SNP) | VAF 33/72 reads (46%) | called by muse, mutect2, varscan2
- LHX9 | c.*1245T>C | 3'UTR (SNP) | VAF 8/44 reads (18%) | called by muse, mutect2, varscan2
- LILRB2 | c.*9G>T | 3'UTR (SNP) | VAF 32/259 reads (12%) | called by muse, mutect2, varscan2
- LINC00654 | n.330C>T | RNA (SNP) | VAF 9/27 reads (33%) | catalogued as rs955554608; called by muse, mutect2, varscan2
- LIPG | c.1482-34C>T | Intron (SNP) | VAF 40/76 reads (53%) | catalogued as rs1471976491; called by muse, mutect2, varscan2
- LRAT | c.*2185T>G | 3'UTR (SNP) | VAF 33/72 reads (46%) | called by muse, mutect2, varscan2
- LTB | c.163-91C>T | Intron (SNP) | VAF 258/416 reads (62%) | catalogued as rs180949041, COSV53002602; called by muse, mutect2, varscan2
- LTB | c.163-154C>G | Intron (SNP) | VAF 132/222 reads (59%) | called by muse, varscan2
- LTB | c.162+169G>A | Intron (SNP) | VAF 47/90 reads (52%) | catalogued as COSV53001174; called by muse, varscan2
- MARCHF11 | c.*70del | 3'UTR (DEL) | VAF 138/257 reads (54%) | catalogued as COSV60133466; called by mutect2, pindel, varscan2
- MARK1 | c.-60dup | 5'UTR (INS) | VAF 11/31 reads (35%) | catalogued as rs1368461508; called by mutect2, pindel, varscan2
- MREG | c.-61G>A | 5'UTR (SNP) | VAF 29/54 reads (54%) | called by muse, mutect2, varscan2
- MSR1 | c.1033+3200G>T | Intron (SNP) | VAF 34/69 reads (49%) | called by muse, mutect2, varscan2
- NAALAD2 | c.1278+381G>T | Intron (SNP) | VAF 74/121 reads (61%) | called by muse, mutect2, varscan2
- P2RY4 | c.*236G>A | 3'UTR (SNP) | VAF 28/33 reads (85%) | called by muse, mutect2, varscan2
- PDE7B | c.*1452G>A | 3'UTR (SNP) | VAF 22/70 reads (31%) | catalogued as rs539861783; called by muse, mutect2, varscan2
- PDXK | c.*4355C>G | 3'UTR (SNP) | VAF 12/26 reads (46%) | called by muse, mutect2, varscan2
- PITPNB | c.*45A>C | 3'UTR (SNP) | VAF 156/343 reads (45%) | called by muse, mutect2, varscan2
- PLEKHH2 | c.*1184G>A | 3'UTR (SNP) | VAF 10/19 reads (53%) | called by muse, mutect2, varscan2
- RAPGEF5 | c.871-155A>G | Intron (SNP) | VAF 13/131 reads (10%) | called by muse, mutect2, varscan2
- SFR1 | c.*277G>C | 3'UTR (SNP) | VAF 5/14 reads (36%) | called by muse, mutect2, varscan2
- SLC38A2 | c.*540T>A | 3'UTR (SNP) | VAF 5/50 reads (10%) | called by mutect2, varscan2
- TMEM63C | c.*931G>A | 3'UTR (SNP) | VAF 8/88 reads (9%) | catalogued as rs1361847016; called by muse, mutect2
- TOR4A | c.*558C>T | 3'UTR (SNP) | VAF 65/192 reads (34%) | catalogued as rs1027609822; called by muse, mutect2, varscan2
- ZNF385C | c.1168-118A>T | Intron (SNP) | VAF 46/89 reads (52%) | called by muse, mutect2, varscan2
